TCGA case TCGA-B8-5162 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: UNC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d62d39f9-c896-4758-a785-e236f0154f14

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 62 years; Vital status: Alive.

Diagnoses (3)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 63.0 years (23,008 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T2a; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Tumor grade: G2; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: Yes.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Sunitinib Malate; Treatment intent type: Neoadjuvant; Days to treatment start: -58 days; Days to treatment end: -28 days; Number of cycles: 1; Prescribed dose: 50; Prescribed dose units: mg/day; Route of administration: Oral.
2. Prior malignancy of the kidney (histology not recorded by GDC). Laterality: Right.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Prostate gland; Classification of tumor: Prior primary; AJCC staging edition: 6th; AJCC pathologic T: T2c; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 22 days; Disease response: Tumor Free.
- Follow-up contact recording only the day: day 36.

Molecular and laboratory tests
- Platelets: Normal.
- Leukocytes: Normal.
- Hemoglobin: Low.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-B8-5162-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.2; Intermediate dimension: 0.4; Shortest dimension: 0.3.
  Slide TCGA-B8-5162-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
  Slide TCGA-B8-5162-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
  Slide TCGA-B8-5162-01A-01-TS2: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 0.
- Sample TCGA-B8-5162-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-B8-5162-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: Yes; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Hemoglobin level: Low; Lymph nodes examined: No; Tobacco smoking history indicator: 1.
- Drug treatment: Regimen number: 1; Pharmaceutical therapy drug name: Sutent; Therapy regimen: OTHER, SPECIFY IN NOTES.
- Drug treatment, Route of administrations: Route of administration: PO.
- Follow-up form 2: Lost to follow-up: Yes; Treatment outcome at TCGA followup: Complete Remission/Response.
- Other malignancy form 1: Malignancy type: Prior Malignancy.
- Other malignancy form 2: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Prostate; Other malignancy histological type: Adenocarcinoma, Not Otherwise Specified.
- Other malignancy form 2, Surgery: Days from index date to other malignancy surgery: -399.

GDC annotations on this case (curator notes; quoted as recorded):
- Neoadjuvant therapy: Prior malignancy R kidney and prostate, no systemic therapy or radiation. Neo-adjuvant sutent given for TCGA tumor.
- Prior malignancy: Subject has Hx of prior malignancy / Subject was positive for neo-adjuvant therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 36 days; disease-specific survival: no event (censored), 36 days; progression-free interval: no event (censored), 36 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-B8-5162-01A-01D-1417-01): tumor purity 0.35, ploidy 1.83, whole-genome doublings 0.
